Gene-level copy-number profile of tumor specimen TCGA-2G-AAIE-01A from TCGA case TCGA-2G-AAIE, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 27.0 years (9,848 days).
Specimen TCGA-2G-AAIE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3d6cb8c8-0779-4ecd-9330-c6732fbafe48.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAIE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/a96ca09b-ec59-40c3-8d43-4b8d04c1e02c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 16; copy number 2: 3,243; copy number 3: 2,046; copy number 4: 20,623; copy number 5: 12,072; copy number 6: 11,110; copy number 7: 6,149; copy number 8: 2,385; copy number 9: 434; copy number 15: 13; copy number 16: 818.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,265 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–522,928, 31 genes, copy number 9: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr7:63,843,314–67,362,950, 150 genes, copy number 9 (broad region; genes not listed).
- chr7:72,558,744–82,657,411, 219 genes, copy number 9 (broad region; genes not listed).
- chr12:66,767–34,249,958, 831 genes, copy number 15–16 (broad region; genes not listed).
- chr22:15,282,557–16,141,872, 34 genes, copy number 9: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1, PSLNR, GRAMD4P2, DUXAP8, AP000526.1, BMS1P22, AP000525.1, DUXAP8, NBEAP3, TOMM40P2, AP000522.1, AC145543.1, U6.

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
